Somatic mutation profile of tumor specimen MP2PRT-PAPFDX-TMP1-A (aliquot MP2PRT-PAPFDX-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFDX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,729 days).
Specimen MP2PRT-PAPFDX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a99c174-fd2a-4952-8226-b4bbec31a607.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFDX-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFDX-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e6eb030-5d45-4aa8-b4a9-dbd8e9c55eae

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 129/330 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FRMPD3 | c.4223C>T p.T1408M | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs772647620, COSV99345759; called by muse, mutect2
- HELZ2 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 219/487 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs761626371, COSV100915641, COSV64410360; called by muse, mutect2, varscan2
- HSH2D | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs749091882; called by muse, mutect2, varscan2
- HSPA12A | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 168/501 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as COSV65023901; called by muse, mutect2, varscan2
- KRTAP10-12 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 213/941 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs782768966; called by muse, varscan2
- MTA1 | c.1897del p.R633Afs*2 | Frame Shift Del (DEL) | VAF 78/437 reads (18%) | catalogued as COSV58760636; called by pindel*, varscan2
- CLDN14 | c.594C>T p.P198= | Silent (SNP) | VAF 156/776 reads (20%) | catalogued as COSV59771665; called by muse, mutect2, varscan2
- RPL10A | c.231T>C p.A77= | Silent (SNP) | VAF 130/426 reads (31%) | called by muse, mutect2, varscan2
- STAG2 | c.3258G>A p.E1086= | Silent (SNP) | VAF 97/258 reads (38%) | catalogued as COSV54361654; called by muse, mutect2, varscan2
